Somatic mutation profile of tumor specimen TCGA-VS-A8Q9-01A (aliquot TCGA-VS-A8Q9-01A-12D-A37N-09) from TCGA case TCGA-VS-A8Q9, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 79.1 years (28,881 days).
Specimen TCGA-VS-A8Q9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77ab0f2b-2db4-43b0-8e49-4d2f58cf622f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8Q9-10A (Blood Derived Normal), aliquot TCGA-VS-A8Q9-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/695f0782-4c55-4f93-8e60-c3c85194909a

The open-access MAF lists 53 somatic variants for this specimen: 33 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 27, Silent 20, Frame Shift Del 2, In Frame Del 1, Splice Region 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs375001140; called by muse, mutect2, varscan2
- ARHGEF2 | c.2671G>A p.D891N (on ENST00000361247 / NM_001162383.2; = p.D863N on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.886); catalogued as rs767282425, COSV100559885; called by muse, mutect2, varscan2
- B3GNT2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs776017170, COSV57345372; called by muse, mutect2, varscan2
- CHEK2 | c.1379T>A p.L460H (on ENST00000382580 / NM_001005735.2; = p.L417H on NM_007194.4) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100100754; called by muse, mutect2, varscan2
- DHX16 | c.2054G>A p.G685D | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99527615; called by muse, mutect2, varscan2
- DIP2B | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.831); catalogued as rs765204962, COSV56578863; called by muse, mutect2, varscan2
- EHD3 | c.43C>G p.P15A | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV100434577; called by muse, mutect2, varscan2
- GTF2IRD2B | c.2126C>T p.T709M | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1554454612; called by muse, mutect2, varscan2
- ITIH3 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs192350744; called by muse, mutect2, varscan2
- KRTAP10-6 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV100551379, COSV59960278; called by muse, mutect2, varscan2
- KXD1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.179); catalogued as rs1458726954, COSV99723598; called by muse, mutect2, varscan2
- MTMR1 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100953765; called by muse, mutect2, varscan2
- MYCBP2 | c.7918G>C p.D2640H (on ENST00000357337; = p.D2678H on NM_015057.5) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV62008909; called by muse, mutect2, varscan2
- MYPN | c.2042C>T p.P681L | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs202084832, COSV100589403; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OCRL | c.1738C>T p.R580W | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1486459755, COSV63980537; called by muse, mutect2, varscan2
- POTEF | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 87/336 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as COSV100664468; called by muse, mutect2, varscan2
- SBF2 | c.5454C>G p.L1818= | Splice Region (SNP) | VAF 29/53 reads (55%) | catalogued as COSV99812715; called by muse, mutect2, varscan2
- STK11 | c.178_179insCA p.Y60Sfs*5 | Frame Shift Ins (INS) | VAF 29/69 reads (42%) | catalogued as CI055775, COSV100479367; called by mutect2, pindel, varscan2
- TMEM241 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as rs1050481181, COSV101271671; called by muse, mutect2, varscan2
- TONSL | c.3242G>A p.R1081Q | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as rs782604369, COSV68049447; called by muse, mutect2, varscan2
- TSC2 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs376285784, CM114653; ClinVar: uncertain significance / likely benign / not provided; called by muse, mutect2, varscan2
- VWA2 | c.1951C>G p.P651A | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100073207; called by muse, mutect2, varscan2
- XAGE5 | c.141G>T p.Q47H | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV100657773; called by muse, mutect2, varscan2
- ZKSCAN7 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99837368; called by muse, mutect2, varscan2
- ZNF362 | c.883C>T p.L295F | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV100986974; called by muse, mutect2, varscan2
- ZNF391 | c.1033A>T p.S345C | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV99772330; called by muse, mutect2, varscan2
- FAT1 | c.6753_6760del p.K2251Nfs*5 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- IGHG1 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- KRTAP10-4 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- LGI1 | c.1499_1500del p.Q500Rfs*3 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- PMAIP1 | c.57_58+22del p.X19_splice | Splice Site (DEL) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- TRAV9-1 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- TRIM58 | c.191_202del p.F64_G68delinsC | In Frame Del (DEL) | VAF 10/17 reads (59%) | called by mutect2, varscan2
- AFMID | c.132C>T p.T44= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV100014753; called by muse, mutect2, varscan2
- CRB1 | c.1872T>C p.G624= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV66334625; called by muse, mutect2, varscan2
- CSPG4 | c.2898G>A p.L966= | Silent (SNP) | VAF 23/176 reads (13%) | catalogued as COSV100413208; called by muse, mutect2, varscan2
- ERBB2 | c.1428C>T p.F476= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs532023577, COSV54070251; called by muse, mutect2, varscan2
- FCRL2 | c.1341C>T p.T447= | Silent (SNP) | VAF 50/120 reads (42%) | catalogued as rs1307461361, COSV100829786; called by muse, mutect2, varscan2
- HDC | c.1305C>T p.L435= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99983738; called by muse, mutect2, varscan2
- ITGA9 | c.1221C>T p.V407= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as rs1482617628, COSV99291241; called by muse, mutect2, varscan2
- LURAP1L | c.183C>T p.S61= | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as COSV100070522; called by muse, mutect2, varscan2
- PADI2 | c.1176C>T p.Y392= | Silent (SNP) | VAF 64/150 reads (43%) | catalogued as rs535364484, COSV64946603; called by muse, mutect2, varscan2
- PLXNA3 | c.3549C>T p.C1183= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs140141994, COSV63756009; called by muse, mutect2, varscan2
- SLC4A10 | c.2016G>A p.P672= (on ENST00000446997 / NM_001354461.2; = p.P642= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs534800788, COSV55798568; called by muse, mutect2, varscan2
- SMARCA4 | c.3558G>A p.A1186= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs140322802; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- SPHKAP | c.2811C>T p.V937= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs1334084304, COSV60876713; called by muse, mutect2, varscan2
- SRPX | c.123C>T p.D41= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as rs768531810, COSV59438113; called by muse, mutect2, varscan2
- STAT5B | c.1755C>G p.L585= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as COSV99510492; called by muse, mutect2, varscan2
- TMEM175 | c.1053C>T p.F351= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs199980539, COSV53277267; called by muse, mutect2, varscan2
- TNRC18 | c.8808G>A p.K2936= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs1360139241, COSV99786565; called by muse, mutect2, varscan2
- TOE1 | c.306C>T p.L102= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as rs1174448118, COSV100516937; called by muse, mutect2, varscan2
- USO1 | c.1176C>T p.F392= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as rs754238263, COSV99362450; called by muse, mutect2, varscan2
- ZIC1 | c.1269G>A p.S423= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs748925382, COSV99291358; called by muse, mutect2, varscan2
